Gene-level copy-number profile of tumor specimen ALCH-B3KB-TTP1-A from ALCHEMIST case ALCH-B3KB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.4 years (24,981 days).
Specimen ALCH-B3KB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e7bddd22-8c5f-4203-9ec1-dc26645ca3a8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3KB-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/3224f08f-0f09-4e7d-acf5-205c132e9f8e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 25,644; copy number 2: 29,419; copy number 3: 3,241; copy number 4: 41; copy number 5: 4; copy number 6: 18; copy number 8: 2; copy number 34: 2.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:5,861,616–5,889,906, 2 genes: ANKRD16, RPL12P28.
- chr14:93,067,452–93,072,152, 1 gene (within-gene range 0–2): ITPK1-AS1.
- chr16:58,665,109–58,684,770, 1 gene: SLC38A7.
- chr17:2,748,078–2,748,182, 2 genes (within-gene range 0–1): MIR1253, hsa-mir-1253.
- chr17:22,298,691–22,332,410, 2 genes: FAM27E5, AC087575.1.
- chr19:2,425,625–2,462,185, 4 genes (within-gene range 0–16): TIMM13, LMNB2, MIR7108, LINC01775.
- chr20:31,580,890–31,581,214, 2 genes: AL110115.2, RNU6-384P.
- chr20:31,637,912–31,645,006, 1 gene: COX4I2.
- chr20:63,272,785–63,289,790, 2 genes: ARFGAP1, MIR4326.
- chr20:64,056,803–64,057,084, 1 gene (within-gene range 0–1): AL355803.1.
- chr20:64,083,380–64,084,359, 1 gene (within-gene range 0–2): LKAAEAR1.
- chr22:18,178,038–18,345,899, 2 genes: FAM230D, GGTLC5P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 26 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:629,239–711,277, 17 genes, copy number 6 (within-gene range 3–6): WFIKKN1, METTL26, MCRIP2, AL022341.1, WDR90, AL022341.2, RHOT2, RHBDL1, LINC02867, Z92544.2, STUB1, JMJD8, WDR24, Z92544.1, FBXL16, Z97653.2, Z97653.1.
- chr16:760,734–768,865, 1 gene, copy number 6: MSLN.
- chr22:18,361,820–18,524,935, 8 genes, copy number 5–34: FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 24,349. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
